Surgical pathology report (de-identified scan), TCGA case TCGA-G5-6233, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G5-6233-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. LOW ANTERIOR RESECTION OF RECTAL CANCER
- B. FINAL DISTAL RECTAL MARGIN

SPECIMEN(S):

- A. LOW ANTERIOR RESECTION OF RECTAL CANCER
- B. FINAL DISTAL RECTAL MARGIN

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

A- An ulcerative tumor mass, 9 x 7 .5 cm, involving the colon circumferentially. 3 cm from the distal margin of resection called by Dr. to Dr. at 1:00 p.m.

GROSS DESCRIPTION:

A. LOW ANTERIOR RESECTION OF RECTAL CANCER

Received fresh is a 30-cm closed segment of colon. The serosa is smooth. There is a suture marking the distal margin; this region is inked black. Specimen is opened; approximately 3 cm from the distal margin is a 9 x 7.5 x 0.4-cm ulcerated, indurated, circumferential mass with serpentine borders which invades the mesocolonic fat. A gross diagnosis was conveyed to O. R. The remainder of the mucosa has numerous diverticuli and 3 polyps, 0.2-0.4 cm. Tissue is procured. Representative sections are submitted as follows:

- A1: proximal margin
- A2: distal margin
- A3-A8: mass and relationship to margins and normal mucosa
- A9: diverticulum
- A10: possible polyps
- A11: normal mucosa
- A12: proximal, 6 lymph nodes
- A13: proximal, 5 lymph nodes
- A14-A16: proximal, 2 lymph nodes each
- A17: proximal, 1 lymph node
- A18-A19: proximal, 1 lymph node
- A20-A24: distal, 6 lymph nodes each
- A25-A26: distal, 2 lymph nodes each
- A27-A28: distal, 1 lymph nodes each
- A29: obstructed mesenteric blood vessel
- ** fat placed in O-Fix for overnight fixation
- A30: proximal, 6 lymph nodes
- A31: proximal, 5 lymph nodes
- A32-A33: proximal, 2 lymph nodes each
- A34-A39: distal, 6 lymph nodes each
- B. FINAL DISTAL RECTAL MARGIN**

Received in formalin is a piece of pink-tan mucosa with surgical staples measuring 2.3 x 1.7 x 0.8 cm. The staples are removed, specimen is bisected, submitted entirely in cassette B1.

DIAGNOSIS:

- A. RECTOSIGMOID COLON, LOW ANTERIOR SEGMENTAL RESECTION:
- INVASIVE MODERATELY DIFFERENTIATED COLONIC ADENOCARCINOMA, 9 X 7.5 X 0.4 CM, INVADING INTO PERIRECTAL ADIPOSE TISSUE.
- MARGINS OF RESECTION ARE NEGATIVE FOR CARCINOMA.
- 27 OF 72 LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (27/72).
- SEE SYNOPTIC REPORT.
- B. DISTAL RECTAL MARGIN, EXCISION:
- COLON TISSUE WITH NO EVIDENCE OF CARCINOMA.

SYNOPTIC REPORT - COLON & RECTUM

Specimens Involved

Specimens: A: LOW ANTERIOR RESECTION OF RECTAL CANCER

Specimen Type: Rectal/rectosigmoid colon (low anterior resection)

Tumor Site: Rectum

[page 2 of 2]
Tumor Configuration: Infiltrative
Ulcerating
Tumor size: 9cm Additional dimensions 7.5cm x 0.4cm
WHO Classification
Adenocarcinoma 8140/3
Histologic Grade: G2: Moderately differentiated
Extent of Invasion: Adjacent structures
Specific Structures: Perirectal adipose tissue.
Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)
Distance of invasive carcinoma from closest margin: 0.4cm
Venous/Lymphatic Invasion: Present
Perineural Invasion: Present
Additional Pathologic Findings: Diverticulosis
Extent of Resection: R0: Complete resection with grossly and microscopically negative margins
Lymph Nodes: Positive 27 / 72
Extranodal extension: Present
Implants: Present
Implants: in pericolic adipose tissue
Pathological Staging (pTNM): pT 3 N 2 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Rectal cancer

Source: NCI Genomic Data Commons file 3432b1b5-08bc-4790-bf40-9ff723c92252 (TCGA-G5-6233.FD37563D-01D8-4321-96E9-7D61CC616407.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).